Somatic mutation profile of tumor specimen TARGET-10-PARFXJ-09A (aliquot TARGET-10-PARFXJ-09A-01D) from TARGET case TARGET-10-PARFXJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.6 years (4,245 days).
Specimen TARGET-10-PARFXJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d66d7956-7b48-47a2-9cda-1f87375fa702.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFXJ-14A (Bone Marrow Normal), aliquot TARGET-10-PARFXJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1ac8032-c2ae-47a8-94ba-0e2393fa684e

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, 5'UTR 2, Nonsense Mutation 2, RNA 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.7327C>T p.R2443* | Nonsense Mutation (SNP) | VAF 40/48 reads (83%) | catalogued as rs121434220, CM960104, COSV53724743, COSV53745412; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC78 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs200865845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGDIA | c.409G>T p.V137F | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV53907175, COSV53907547; called by muse, mutect2, varscan2
- CNOT3 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55360199; called by muse, mutect2, varscan2
- COL19A1 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150657474; called by muse, mutect2, varscan2
- EHBP1 | c.1538G>A p.S513N | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs1271000400; called by muse, mutect2
- JAK1 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.296); catalogued as COSV61089562; called by muse, mutect2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- LCA5 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63972693; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- PLAAT1 | c.764T>G p.V255G (on ENST00000650797; = p.V150G on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV53232789; called by muse, mutect2, varscan2
- PTPN21 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1185375048, COSV60850312; called by muse, mutect2
- PYGM | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs368077182; called by muse, mutect2, varscan2
- RPGRIP1L | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs1296403401, COSV50902601; called by muse, mutect2, varscan2
- TMEM132C | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 36/66 reads (55%) | catalogued as rs1244363099, COSV59416276; called by muse, mutect2, varscan2
- UNC45A | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.039); catalogued as COSV57746649; called by muse, mutect2, varscan2
- VWF | c.4277G>A p.R1426H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs761308466, COSV54630917; called by muse, mutect2, varscan2
- GP9 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SUMO2 | c.226-1G>C p.X76_splice | Splice Site (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- ADCY9 | c.3258C>T p.N1086= | Silent (SNP) | VAF 73/145 reads (50%) | catalogued as rs774669255; called by muse, mutect2, varscan2
- HARS2 | c.120A>G p.A40= | Silent (SNP) | VAF 51/123 reads (41%) | called by muse, mutect2, varscan2
- SRRT | c.1353G>A p.A451= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs748054287; called by muse, mutect2, varscan2
- GRM1 | c.-34C>T | 5'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99266102; called by muse, mutect2, varscan2
- OPCML | c.-54G>A | 5'UTR (SNP) | VAF 27/71 reads (38%) | catalogued as rs544096790, COSV59453989; called by muse, mutect2, varscan2
- PSMG3-AS1 | n.4088T>C | RNA (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- SEC14L5 | c.*68G>A | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2
